Surgical pathology report (de-identified scan), TCGA case TCGA-A3-3320, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-3320-01A (Primary Tumor).

[page 1 of 2]
Laboratory Patient Report
Print Date/Time: [REDACTED]

Surgical Pathology

Histopathological Examination

Path#: [REDACTED]
Collected: [REDACTED] Received [REDACTED] Complete: [REDACTED]

Pre-Op Diagnosis : Right Renal Mass
Order Physician [REDACTED]
Specimens : Kidney, Right
Frozen Diagnosis :

Report : GROSS EXAMINATION.
The specimen is received in a container labeled with the name of the patient and labeled as kidney, right. The specimen consists of a kidney and attached perinephric fat which measures en bloc 15 x 8 x 6 cm and weighs 373 g. The ureter and vascular margins of resection are submitted in block 1. The kidney is bivalved and shut is an oval golden yellow mass at the lower pole. The mass measures 5.0 x 5.0 x 4.0 cm. The mass is focally adherent to the capsule but does not grossly extent through the capsule. Sections of the capsule overlying the mass are submitted in block 2. Sections of the mass are submitted in blocks 3-8. The pelvis and calyces are not grossly dilated. The cortex averages 0.6 cm. A random section of kidney is submitted in block 9. Sectioning through the attached fat shows no adrenal tissue or lymph nodes. [REDACTED]

DIAGNOSIS BASED ON GROSS AND MICROSCOPIC EXAMINATION:
Right kidney: Clear cell renal cell carcinoma, Fuhrman Grade I of IV, 5 cm greatest diameter.
No capsule invasion.
No blood vessel invasion.
Ureter segment identified.
[T-71000 M-83103 189.0 P3-44070]

PATHOLOGIC STAGE: pT1b,NX,MX Stage I

Intradepartmental consultation obtained.

[REDACTED] Pathologist

Electronically Signed by:

THIS CONFIDENTIAL AND PRIVILEGED DOCUMENT/INFORMATION IS PROTECTED BY
FEDERAL AND STATE LAW. UNAUTHORIZED DISCLOSURE, DISSEMINATION
OR DUPLICATION IS PROHIBITED

[page 2 of 2]
THIS CONFIDENTIAL AND PRIVILEGED DOCUMENT/INFORMATION IS PROTECTED BY
FEDERAL AND STATE LAW. UNAUTHORIZED DISCLOSURE, DISSEMINATION
OR DUPLICATION IS PROHIBITED

MR#: [REDACTED]

Path #: [REDACTED]
Visit #: [REDACTED]

Source: NCI Genomic Data Commons file 8ea59a3f-bacd-49ac-a1c3-7c35580e81ad (TCGA-A3-3320.7DF3FDC1-6D54-4EC7-828C-71799B083741.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).